Somatic mutation profile of tumor specimen TCGA-AA-A00N-01A (aliquot TCGA-AA-A00N-01A-02D-A17O-10) from TCGA case TCGA-AA-A00N, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIB; Age at diagnosis: 75.7 years (27,667 days).
Specimen TCGA-AA-A00N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2566150-da6f-4958-95bb-793ec880d733.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-A00N-10A (Blood Derived Normal), aliquot TCGA-AA-A00N-10A-01D-A17O-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8de23acc-2a2d-4de2-9abb-76196080a75d

The open-access MAF lists 6,019 somatic variants for this specimen: 4,296 protein-altering or splice-affecting, 1,204 silent, 519 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3,749, Silent 1,204, Nonsense Mutation 429, 3'UTR 220, Intron 151, RNA 67, Splice Region 54, 5'UTR 45, Splice Site 39, 3'Flank 19, 5'Flank 17, Frame Shift Ins 13.

Variants (750 of 6,019; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH3A2 | c.551C>T p.T184M | Missense Mutation (SNP) | VAF 102/376 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs72547562, CM993307, CM993308; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APC | c.4222G>T p.E1408* | Nonsense Mutation (SNP) | VAF 39/133 reads (29%) | hotspot (GDC flag); catalogued as CM106374, COSV57326063, COSV57397024; called by muse, mutect2, varscan2
- ATM | c.5188C>T p.R1730* | Nonsense Mutation (SNP) | VAF 62/211 reads (29%) | catalogued as rs764389018, CM990211, COSV53730827; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CC2D2A | c.3850C>T p.R1284C | Missense Mutation (SNP) | VAF 59/218 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779823379, CM120107, COSV67502170; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CEP290 | c.4966G>T p.E1656* | Nonsense Mutation (SNP) | VAF 29/170 reads (17%) | catalogued as rs62638179, CM063894, COSV58350032; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- CHD3 | c.2896C>T p.R966W | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1064795892, COSV57873444; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- CREBBP | c.4337G>A p.R1446H | Missense Mutation (SNP) | VAF 27/87 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519884, COSV52112787, COSV52125401, COSV52132241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DNAH11 | c.6004C>T p.R2002* | Nonsense Mutation (SNP) | VAF 41/196 reads (21%) | catalogued as rs373844629; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNMT1 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 29/144 reads (20%) | hotspot (GDC flag); SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as rs751093624, COSV61576638; called by muse, mutect2, varscan2
- DOCK8 | c.949C>T p.R317* | Nonsense Mutation (SNP) | VAF 20/86 reads (23%) | catalogued as rs113432057, CM098841; ClinVar: pathogenic; called by muse, varscan2
- EYS | c.4045C>T p.R1349* | Nonsense Mutation (SNP) | VAF 29/109 reads (27%) | catalogued as rs930421180, CM1312776; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- F2 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs121918484, CM000011, COSV61314756, COSV61318092; ClinVar: pathogenic; called by muse, mutect2, varscan2
- F8 | c.5593G>T p.D1865Y | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28933678, CM960560, CM960561, COSV64279265; ClinVar: pathogenic; called by mutect2, varscan2
- FOXG1 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786205007, CM1210351, COSV57398603; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GLA | c.679C>T p.R227* | Nonsense Mutation (SNP) | VAF 66/190 reads (35%) | catalogued as rs104894841, CM930329, COSV54510711; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GLDC | c.1723G>T p.E575* | Nonsense Mutation (SNP) | VAF 21/121 reads (17%) | catalogued as rs1554646529, COSV58685784; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- GLI1 | c.1139G>A p.R380Q | Missense Mutation (SNP) | VAF 17/91 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1381253752, COSV57357760; called by muse, mutect2, varscan2
- GUCY2C | c.2008G>A p.A670T | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.22); catalogued as rs587784572, CM155720, COSV53787172; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HSD3B7 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 54/254 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104894518, CM031220, COSV52680560; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IFIH1 | c.2335C>T p.R779C | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587777448, CM144546, COSV55125315; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 42/248 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MMADHC | c.160C>T p.R54* | Nonsense Mutation (SNP) | VAF 25/77 reads (32%) | catalogued as rs118204047, CM081191, COSV57574342; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH2 | c.1738G>T p.E580* | Nonsense Mutation (SNP) | VAF 66/340 reads (19%) | hotspot (GDC flag); catalogued as rs63751411, CM981314, COSV51876952; ClinVar: pathogenic; called by muse, varscan2
- MSH6 | c.2836G>T p.E946* | Nonsense Mutation (SNP) | VAF 19/87 reads (22%) | catalogued as rs1558666905, COSV52274084; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NPHS2 | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 20/144 reads (14%) | catalogued as rs1057516414, CM141333, COSV62635208; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NR3C2 | c.2453C>T p.S818L | Missense Mutation (SNP) | VAF 59/237 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs121912573, CM065346, CM124521, COSV61000655; ClinVar: pathogenic; called by muse, varscan2
- OTC | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 88/181 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs66550389, CM062966, CM062967, CM910275, COSV50000649, COSV50002957; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PGR | c.2507G>A p.R836Q | Missense Mutation (SNP) | VAF 9/59 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs1000609240, COSV54795429; called by muse, mutect2
- PIK3CA | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 37/189 reads (20%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen possibly damaging (0.728); catalogued as COSV55885255, COSV55891864; called by muse, mutect2, varscan2
- PIK3CA | c.3062A>G p.Y1021C | Missense Mutation (SNP) | VAF 9/69 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913288, CM126695, COSV55882161, COSV55997924; ClinVar: likely pathogenic; called by mutect2, varscan2
- POLE | c.1231G>T p.V411L | Missense Mutation (SNP) | VAF 22/91 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519945, COSV57676103, COSV57677068, COSV57683938; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PROM1 | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as rs137853006, CM083044, COSV101477144, COSV71699500; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RAG1 | c.2690G>A p.R897Q | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1064793249, COSV55026579; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.1129C>T p.R377* | Nonsense Mutation (SNP) | VAF 18/105 reads (17%) | catalogued as rs794726799, CM067015, COSV57667265; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN5A | c.2204C>T p.A735V | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs137854611, CM020302, CM024639, COSV100351382, COSV61142041; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TGFBR1 | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 16/122 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs111854391, CM061221, COSV66624834; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TP63 | c.1780C>T p.R594* | Nonsense Mutation (SNP) | VAF 18/182 reads (10%) | catalogued as rs900140738, COSV53196111; ClinVar: pathogenic; called by muse, mutect2
- TSC22D2 | c.2204C>A p.S735Y | Missense Mutation (SNP) | VAF 42/212 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62622374, COSV62622441; called by muse, mutect2, varscan2
- A2M | c.2195G>A p.R732Q | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1259395599, COSV59385400; called by muse, mutect2, varscan2
- A2M | c.1615C>T p.R539W | Missense Mutation (SNP) | VAF 59/261 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs780559648, COSV104404246; called by muse, mutect2, varscan2
- A2M | c.572C>A p.S191Y | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV59393078; called by muse, mutect2, varscan2
- A2ML1 | c.3458G>T p.R1153I | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100229590; called by muse, mutect2
- A2ML1 | c.4034G>A p.R1345Q | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs1388303934, COSV55285428; called by muse, mutect2
- A4GNT | c.537G>T p.E179D | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV52630085; called by muse, mutect2, varscan2
- AADAC | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV51761634; called by muse, mutect2
- AADACL4 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.086); catalogued as rs139261871; called by muse, mutect2, varscan2
- AASDH | c.1484A>C p.E495A | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.019); catalogued as rs763378158, COSV52711111; called by muse, mutect2, varscan2
- ABCA1 | c.2471C>T p.S824L | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.763); catalogued as rs551884479, CM1210656, COSV66064183; called by muse, mutect2, varscan2
- ABCA1 | c.2339G>A p.S780N | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs143626002; called by muse, mutect2, varscan2
- ABCA10 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.094); catalogued as rs745423957, COSV52230478; called by muse, mutect2, varscan2
- ABCA12 | c.271G>T p.D91Y | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV55954144; called by muse, mutect2, varscan2
- ABCA5 | c.4427G>A p.R1476Q | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as rs750426352, COSV67015792; called by muse, mutect2
- ABCA5 | c.3688A>C p.K1230Q | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.132); catalogued as COSV67017929, COSV67019351; called by muse, mutect2, varscan2
- ABCA5 | c.259A>C p.I87L | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as COSV67019356; called by muse, mutect2, varscan2
- ABCA6 | c.4160C>T p.A1387V | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.207); catalogued as rs527461596, COSV52641428; called by muse, mutect2
- ABCA6 | c.2314A>G p.T772A | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.78); PolyPhen benign (0.019); catalogued as COSV52637805; called by muse, mutect2, varscan2
- ABCA8 | c.2405G>A p.R802Q | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV52201741; called by muse, mutect2, varscan2
- ABCB1 | c.90G>T p.K30N | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as COSV55950310; called by muse, mutect2, varscan2
- ABCB11 | c.3716T>C p.I1239T | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55602496; called by muse, mutect2, varscan2
- ABCB5 | c.1085T>C p.V362A | Missense Mutation (SNP) | VAF 64/186 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV51722166; called by muse, mutect2, varscan2
- ABCB6 | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1195119096; called by muse, mutect2, varscan2
- ABCB7 | c.1253T>G p.F418C (on ENST00000373394 / NM_001271696.3; = p.F419C on NM_004299.6) | Missense Mutation (SNP) | VAF 54/110 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53724248; called by muse, mutect2, varscan2
- ABCC12 | c.890A>C p.K297T | Missense Mutation (SNP) | VAF 50/174 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.139); catalogued as COSV60918731; called by muse, mutect2, varscan2
- ABCC4 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.035); catalogued as rs1415738240, COSV65313177; called by muse, mutect2, varscan2
- ABCD2 | c.1634A>G p.Y545C | Missense Mutation (SNP) | VAF 34/196 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58055535; called by muse, varscan2
- ABCD3 | c.742C>T p.R248* | Nonsense Mutation (SNP) | VAF 10/130 reads (8%) | catalogued as rs1299713122; called by muse, mutect2
- ABCD3 | c.1168C>T p.R390W | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757515840, COSV64644762; called by muse, mutect2, varscan2
- ABCG4 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1410189384, COSV56646016; called by muse, mutect2, varscan2
- ABHD2 | c.914A>G p.D305G | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV61776563; called by muse, varscan2
- ABHD4 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs755342789, COSV53530796; called by muse, mutect2, varscan2
- ABHD4 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 100/370 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs368142560; called by muse, varscan2
- ABL2 | c.2050G>A p.E684K (on ENST00000502732 / NM_007314.4; = p.E669K on NM_005158.5) | Missense Mutation (SNP) | VAF 52/282 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.056); catalogued as COSV61012829; called by muse, mutect2, varscan2
- ABT1 | c.120G>T p.K40N | Missense Mutation (SNP) | VAF 102/390 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.286); catalogued as rs1554144553; called by muse, mutect2, varscan2
- ABT1 | c.292A>C p.K98Q | Missense Mutation (SNP) | VAF 56/188 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.216); catalogued as COSV51293449; called by muse, mutect2, varscan2
- AC004922.1 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 53/331 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs1032525792, COSV53559564; called by muse, mutect2, varscan2
- AC053503.6 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as rs775387737; called by muse, mutect2, varscan2
- AC055839.2 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.29); catalogued as rs1383266374; called by muse, mutect2
- ACAD11 | c.1212C>A p.F404L | Missense Mutation (SNP) | VAF 37/206 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.586); catalogued as COSV53901135; called by muse, mutect2, varscan2
- ACAN | c.5317C>A p.L1773I | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.661); catalogued as rs767359295, COSV61357916, COSV61369764; called by muse, mutect2, varscan2
- ACAP1 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs778742775, COSV50139602; called by muse, mutect2, varscan2
- ACBD3 | c.373A>C p.N125H | Missense Mutation (SNP) | VAF 145/710 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64731384; called by muse, mutect2, varscan2
- ACBD6 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 59/186 reads (32%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.849); catalogued as rs762191597, COSV62575798; called by muse, mutect2, varscan2
- ACCS | c.1250G>T p.R417I | Missense Mutation (SNP) | VAF 79/470 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV55460532; called by muse, mutect2, varscan2
- ACE2 | c.1874A>C p.K625T | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as COSV99383161; called by muse, mutect2
- ACER1 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.751); catalogued as rs759458903, COSV56836321; called by muse, mutect2, varscan2
- ACLY | c.3166G>A p.A1056T | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.011); catalogued as COSV59863227; called by muse, mutect2, varscan2
- ACO1 | c.1004A>C p.K335T | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV59385325; called by muse, varscan2
- ACOD1 | c.977C>T p.S326L | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs549181296; called by muse, mutect2, varscan2
- ACOT1 | c.261G>T p.E87D | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100233464; called by muse, mutect2, varscan2
- ACOT12 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56897277; called by muse, mutect2, varscan2
- ACRBP | c.175A>G p.T59A | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.034); catalogued as COSV57525563; called by muse, mutect2, varscan2
- ACSBG1 | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | catalogued as COSV51911410; called by muse, mutect2, varscan2
- ACSBG2 | c.738C>T p.N246= | Splice Region (SNP) | VAF 26/90 reads (29%) | catalogued as rs560299046, COSV53123538; called by muse, mutect2, varscan2
- ACSL1 | c.1835C>T p.A612V | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.178); catalogued as COSV55666927; called by muse, mutect2, varscan2
- ACSL1 | c.34A>G p.M12V | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV55666940; called by muse, mutect2, varscan2
- ACSM1 | c.665T>C p.V222A | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54638199; called by muse, mutect2
- ACSS2 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 40/203 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as rs757812388, COSV53628675; called by muse, mutect2, varscan2
- ACSS3 | c.1900C>T p.R634* | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | catalogued as rs776097345, COSV54091174; called by mutect2, varscan2
- ACTL6A | c.402G>T p.E134D | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV66999539; called by muse, mutect2, varscan2
- ACTN2 | c.1982C>T p.A661V | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.122); catalogued as rs1357678813, COSV63978576; called by muse, mutect2, varscan2
- ACTR3B | c.687G>A p.E229= | Splice Region (SNP) | VAF 26/476 reads (5%) | catalogued as COSV99754647; called by muse, mutect2
- ACTRT1 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV100947781, COSV64419695; called by muse, mutect2
- ACTRT2 | c.663C>A p.C221* | Nonsense Mutation (SNP) | VAF 30/198 reads (15%) | catalogued as COSV65758944, COSV65760292; called by muse, mutect2, varscan2
- ADAD1 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs13106730, COSV56641069; called by muse, mutect2, varscan2
- ADAM12 | c.573G>T p.K191N | Missense Mutation (SNP) | VAF 44/246 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100901219, COSV64115506, COSV64116287; called by muse, mutect2, varscan2
- ADAM17 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs1398583399, COSV60402089; called by muse, mutect2, varscan2
- ADAM2 | c.1351G>T p.E451* | Nonsense Mutation (SNP) | VAF 19/138 reads (14%) | catalogued as COSV55860650, COSV55869098; called by muse, mutect2
- ADAM21 | c.807G>T p.M269I | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV50813258; called by muse, mutect2, varscan2
- ADAM21 | c.905C>A p.S302* | Nonsense Mutation (SNP) | VAF 10/94 reads (11%) | catalogued as COSV50812063, COSV50813379; called by muse, mutect2, varscan2
- ADAM22 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.07); catalogued as rs779354391, COSV55990094; called by muse, mutect2
- ADAM28 | c.586G>T p.D196Y | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV56106151; called by mutect2, varscan2
- ADAM28 | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.554); catalogued as COSV56106160; called by muse, mutect2, varscan2
- ADAM7 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as rs137990671, COSV51537987; called by muse, mutect2, varscan2
- ADAMTS12 | c.4155G>T p.K1385N | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.176); catalogued as COSV100711500, COSV61257474, COSV61281671; called by muse, mutect2, varscan2
- ADAMTS12 | c.2894G>A p.R965Q | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.28); catalogued as rs563669246, COSV100711796, COSV61255980; called by muse, mutect2, varscan2
- ADAMTS12 | c.820A>G p.I274V | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.669); catalogued as COSV61281689; called by muse, mutect2
- ADAMTS16 | c.818C>A p.S273Y | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56983360, COSV57008597; called by muse, mutect2, varscan2
- ADAMTS18 | c.1145G>T p.R382I | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51402028; called by muse, mutect2, varscan2
- ADAMTS19 | c.1465G>T p.E489* | Nonsense Mutation (SNP) | VAF 27/98 reads (28%) | catalogued as COSV50805176; called by muse, mutect2, varscan2
- ADAMTS19 | c.3555G>T p.K1185N | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.913); catalogued as COSV50805247; called by muse, mutect2
- ADAMTS20 | c.3496G>A p.V1166I | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.438); catalogued as rs538139197, COSV67140479; called by muse, mutect2, varscan2
- ADAMTS5 | c.1310G>A p.R437H | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (1); PolyPhen possibly damaging (0.501); catalogued as rs367992476, COSV53177630; called by muse, mutect2, varscan2
- ADAMTS9 | c.4391G>A p.R1464Q | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1017604051; called by muse, varscan2
- ADAMTS9 | c.2461C>T p.R821C | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs1464529267, COSV55785517; called by muse, mutect2
- ADCK2 | c.1348A>C p.N450H | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50783795; called by muse, mutect2, varscan2
- ADCY8 | c.3500C>T p.T1167M | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1356343883, COSV53897190; called by muse, mutect2, varscan2
- ADCY8 | c.3060+1G>A p.X1020_splice | Splice Site (SNP) | VAF 16/94 reads (17%) | catalogued as COSV99654706; called by muse, varscan2
- ADCY8 | c.1835G>T p.R612I | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.276); catalogued as COSV53928701, COSV53930321; called by muse, mutect2, varscan2
- ADGRA2 | c.2119G>A p.E707K | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as rs200831475; called by mutect2, varscan2
- ADGRA3 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 58/219 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as rs776366061, COSV57546319; called by muse, mutect2, varscan2
- ADGRB3 | c.2741T>G p.L914R | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53253084; called by muse, mutect2, varscan2
- ADGRD2 | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs1274838000, COSV58339191; called by muse, mutect2, varscan2
- ADGRE1 | c.1106C>T p.T369I | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as rs145287041; called by muse, varscan2
- ADGRE1 | c.1115C>A p.S372Y | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51672708, COSV51674277; called by muse, varscan2
- ADGRE5 | c.819+2T>C p.X273_splice (on ENST00000242786 / NM_078481.4; = p.X180_splice on NM_001784.5) | Splice Site (SNP) | VAF 22/244 reads (9%) | catalogued as COSV54415391, COSV99663383; called by muse, mutect2, varscan2
- ADGRF5 | c.3232C>T p.R1078C | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.616); catalogued as rs1196481373, COSV51930188; called by muse, mutect2, varscan2
- ADGRF5 | c.3133C>T p.R1045W | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs200682859, COSV51930087; called by muse, mutect2, varscan2
- ADGRG2 | c.73C>A p.L25I | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.411); catalogued as COSV61341636; called by muse, mutect2, varscan2
- ADGRG4 | c.2207T>A p.F736Y | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV54958376, COSV99797404; called by muse, mutect2, varscan2
- ADGRG4 | c.7010G>A p.S2337N | Missense Mutation (SNP) | VAF 63/122 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1195559174, COSV54968242; called by muse, mutect2, varscan2
- ADGRL2 | c.3424G>T p.D1142Y (on ENST00000370717 / NM_001366005.1; = p.D1129Y on NM_012302.4) | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54691626, COSV99588253; called by muse, mutect2, varscan2
- ADGRL3 | c.1511G>T p.G504V (on ENST00000506720 / NM_001322402.2; = p.G436V on NM_015236.6) | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV72232082; called by muse, mutect2, varscan2
- ADGRL3 | c.3752G>A p.R1251Q (on ENST00000506720 / NM_001322402.2; = p.R1183Q on NM_015236.6) | Missense Mutation (SNP) | VAF 36/189 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1189094336, COSV72229226; called by muse, mutect2, varscan2
- ADGRV1 | c.3224T>G p.F1075C | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.969); catalogued as COSV67996453; called by muse, mutect2, varscan2
- ADGRV1 | c.13424A>G p.D4475G | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.339); catalogued as COSV67996454; called by muse, mutect2
- ADGRV1 | c.18121T>C p.S6041P | Missense Mutation (SNP) | VAF 71/337 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67996456; called by muse, mutect2, varscan2
- ADHFE1 | c.1013G>T p.G338V | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52559574; called by muse, mutect2, varscan2
- ADIPOQ | c.293A>G p.Q98R | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.8); PolyPhen benign (0.334); catalogued as rs1395173605, COSV100292270; called by muse, mutect2, varscan2
- ADSL | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 39/227 reads (17%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.584); catalogued as rs745787396, COSV53410811; ClinVar: uncertain significance; called by muse, varscan2
- ADSL | c.358-5C>T | Splice Region (SNP) | VAF 56/196 reads (29%) | catalogued as rs769856337, COSV53408962; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADSS2 | c.1288C>T p.R430* | Nonsense Mutation (SNP) | VAF 36/151 reads (24%) | catalogued as COSV63694640, COSV63695668; called by muse, mutect2, varscan2
- AFAP1L2 | c.1959G>A p.E653= | Splice Region (SNP) | VAF 8/112 reads (7%) | catalogued as COSV100413087; called by muse, mutect2
- AFF1 | c.3004G>T p.G1002* | Nonsense Mutation (SNP) | VAF 44/139 reads (32%) | catalogued as COSV57124986; called by muse, mutect2, varscan2
- AFF2 | c.388A>G p.T130A | Missense Mutation (SNP) | VAF 29/274 reads (11%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.987); catalogued as COSV60682973; called by muse, mutect2, varscan2
- AFF2 | c.2471C>T p.A824V | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV54009382; called by muse, mutect2, varscan2
- AFF3 | c.755A>C p.K252T | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57875692; called by muse, mutect2, varscan2
- AFG1L | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as rs944399722, COSV64558646; called by muse, mutect2, varscan2
- AFG3L2 | c.2132G>T p.R711I | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as rs1399438718, COSV52312988, COSV52316117; called by muse, mutect2, varscan2
- AGAP1 | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV58325321; called by muse, mutect2, varscan2
- AGAP3 | c.1135G>A p.G379S (on ENST00000622464; = p.G415S on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.29); PolyPhen probably damaging (1); catalogued as rs535196546; called by muse, mutect2, varscan2
- AGBL3 | c.1747G>T p.E583* | Nonsense Mutation (SNP) | VAF 15/67 reads (22%) | catalogued as COSV51949460; called by muse, mutect2, varscan2
- AGBL4 | c.1022A>G p.N341S | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as rs752378443, COSV61896203; called by muse, mutect2, varscan2
- AGBL5 | c.2606C>A p.P869H | Missense Mutation (SNP) | VAF 66/359 reads (18%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV64080925; called by muse, mutect2, varscan2
- AGFG1 | c.821G>T p.S274I | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as COSV59515073; called by muse, mutect2, varscan2
- AGO1 | c.2555G>A p.R852H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100940932; called by muse, mutect2, varscan2
- AHNAK | c.7799C>A p.S2600Y | Missense Mutation (SNP) | VAF 36/205 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV57208598, COSV57232904; called by muse, mutect2, varscan2
- AHNAK2 | c.13756G>A p.D4586N | Missense Mutation (SNP) | VAF 53/169 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); catalogued as rs559049528, COSV60917301; called by muse, mutect2, varscan2
- AHNAK2 | c.13486G>A p.D4496N | Missense Mutation (SNP) | VAF 66/237 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.847); catalogued as rs760149560, COSV60912529; called by muse, mutect2, varscan2
- AIFM1 | c.1658C>T p.A553V | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99781485; called by muse, mutect2
- AK5 | c.1283T>G p.I428S (on ENST00000354567 / NM_174858.3; = p.I402S on NM_012093.4) | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs143683857, COSV60982521; called by muse, mutect2, varscan2
- AK7 | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774815872, COSV50876171; called by muse, mutect2, varscan2
- AK7 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as rs149622950, COSV50869271, COSV50871563; called by muse, mutect2, varscan2
- AK7 | c.2042G>A p.R681K | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV50876091, COSV50884061; called by muse, mutect2, varscan2
- AK9 | c.4204C>T p.R1402C | Missense Mutation (SNP) | VAF 69/366 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs1029844116; called by muse, mutect2, varscan2
- AK9 | c.3076C>A p.L1026I | Missense Mutation (SNP) | VAF 69/249 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58143321; called by muse, mutect2, varscan2
- AK9 | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 35/157 reads (22%) | catalogued as rs201060409, COSV53424497; called by muse, mutect2, varscan2
- AKAP6 | c.1308A>C p.K436N | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55235316; called by muse, mutect2, varscan2
- AKAP6 | c.3582G>T p.K1194N | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV55235330; called by muse, mutect2, varscan2
- AKAP6 | c.5258G>A p.S1753N | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1225291138; called by muse, mutect2
- AKAP9 | c.1081G>T p.E361* | Nonsense Mutation (SNP) | VAF 57/353 reads (16%) | catalogued as COSV62358986; called by muse, mutect2, varscan2
- AKAP9 | c.3349C>T p.R1117C | Missense Mutation (SNP) | VAF 52/197 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1277410775, COSV62358994; called by muse, mutect2, varscan2
- AKAP9 | c.10321C>T p.R3441C (on ENST00000359028; = p.R3417C on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/222 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.944); catalogued as rs146495719; ClinVar: likely benign; called by muse, mutect2, varscan2
- AKAP9 | c.11495A>G p.E3832G (on ENST00000359028; = p.E3808G on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV99134188; called by muse, mutect2, varscan2
- AKR1A1 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100698797; called by muse, mutect2, varscan2
- AL049569.3 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 55/274 reads (20%) | PolyPhen possibly damaging (0.833); catalogued as rs762883769; called by muse, mutect2, varscan2
- ALAD | c.575C>T p.S192L | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs761010522; called by muse, mutect2, varscan2
- ALB | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.041); catalogued as rs774294755, COSV55738750, COSV55739357; called by muse, mutect2, varscan2
- ALDH5A1 | c.363T>G p.S121R | Missense Mutation (SNP) | VAF 74/298 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV62374649; called by muse, mutect2, varscan2
- ALG10 | c.176A>G p.D59G | Missense Mutation (SNP) | VAF 91/486 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56794369; called by muse, mutect2, varscan2
- ALG10 | c.1021A>G p.T341A | Missense Mutation (SNP) | VAF 89/503 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56794380; called by muse, mutect2, varscan2
- ALG2 | c.905C>A p.S302Y | Missense Mutation (SNP) | VAF 53/259 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53058670; called by muse, varscan2
- ALK | c.4319C>T p.A1440V | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV66578548; called by muse, mutect2, varscan2
- ALLC | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 49/237 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.908); catalogued as rs756768853, COSV52998569; called by muse, mutect2, varscan2
- ALLC | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 54/245 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as COSV52998585; called by muse, mutect2, varscan2
- ALMS1 | c.3369T>G p.I1123M | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); catalogued as COSV52523205; called by muse, mutect2, varscan2
- ALOX15B | c.1381C>T p.R461W | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs753001193, COSV66480245; called by muse, mutect2, varscan2
- ALOXE3 | c.363T>G p.I121M | Missense Mutation (SNP) | VAF 70/271 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as COSV59078278; called by muse, mutect2, varscan2
- ALPK2 | c.2513T>C p.V838A | Missense Mutation (SNP) | VAF 71/241 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as COSV64497718; called by muse, mutect2, varscan2
- ALPK2 | c.55C>A p.L19I | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as COSV64497726; called by muse, mutect2, varscan2
- ALPK3 | c.3287C>T p.S1096F | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV99362112; called by muse, mutect2
- ALS2 | c.2363C>A p.S788Y | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.828); catalogued as COSV51893456; called by muse, mutect2, varscan2
- ALS2 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 59/274 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.477); catalogued as COSV51893464; called by muse, mutect2, varscan2
- AMDHD1 | c.616G>T p.D206Y | Missense Mutation (SNP) | VAF 17/207 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as COSV57140655, COSV99900529; called by muse, mutect2
- AMFR | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 53/222 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.297); catalogued as rs750744117, COSV51924688; called by muse, mutect2, varscan2
- AMIGO2 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV56973669; called by muse, mutect2, varscan2
- AMIGO2 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 65/295 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as rs865785572, COSV56975699; called by muse, mutect2, varscan2
- AMOTL1 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV58566090; called by muse, mutect2, varscan2
- AMOTL1 | c.2047G>A p.D683N | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs752948602, COSV58571276; called by muse, mutect2, varscan2
- AMPD1 | c.1506G>T p.K502N | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.93); catalogued as COSV62416866; called by muse, mutect2, varscan2
- AMPH | c.1594G>T p.A532S | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.092); catalogued as COSV57759094; called by muse, mutect2, varscan2
- AMPH | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs151055033; called by muse, mutect2, varscan2
- AMY1C | c.938A>G p.N313S | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100915248, COSV64407089; called by muse, mutect2, varscan2
- ANAPC4 | c.463A>C p.I155L | Missense Mutation (SNP) | VAF 40/187 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV59544154, COSV59546522; called by muse, mutect2, varscan2
- ANGEL2 | c.806A>G p.N269S | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (0.85); PolyPhen benign (0.03); catalogued as rs1255078851, COSV64738469; called by muse, varscan2
- ANGPTL2 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs191786568, COSV52233848; called by muse, mutect2, varscan2
- ANK1 | c.2971G>A p.V991M | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs758454168, COSV55875928; called by muse, mutect2, varscan2
- ANK1 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as rs376057905, COSV55880088; called by muse, mutect2, varscan2
- ANK3 | c.12320-1G>T p.X4107_splice (on ENST00000280772 / NM_001320874.2; = p.X628_splice on NM_001149.3) | Splice Site (SNP) | VAF 7/24 reads (29%) | catalogued as COSV99782726; called by muse, mutect2
- ANK3 | c.2063C>T p.A688V | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769188895, COSV55084703; called by muse, mutect2, varscan2
- ANKFN1 | c.1573C>T p.L525F | Missense Mutation (SNP) | VAF 45/228 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59461168; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.6059C>A p.S2020Y | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.365); catalogued as COSV51859752; called by muse, mutect2, varscan2
- ANKIB1 | c.2110C>T p.R704C | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.525); catalogued as rs1205246827, COSV56066547; called by muse, mutect2, varscan2
- ANKLE2 | c.433C>A p.P145T | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.07); catalogued as rs752920481, COSV61712006; called by muse, mutect2, varscan2
- ANKRD12 | c.94G>T p.D32Y | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV50845904; called by muse, mutect2
- ANKRD13C | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.895); catalogued as rs774093011, COSV52035716; called by mutect2, varscan2
- ANKRD17 | c.3220G>T p.D1074Y | Missense Mutation (SNP) | VAF 42/242 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV58228585; called by muse, mutect2, varscan2
- ANKRD26 | c.5045C>A p.S1682Y | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.515); catalogued as COSV65778762; called by muse, mutect2, varscan2
- ANKRD26 | c.4208A>G p.K1403R | Missense Mutation (SNP) | VAF 82/432 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.121); catalogued as COSV65778767; called by muse, varscan2
- ANKRD26 | c.4126G>A p.E1376K | Missense Mutation (SNP) | VAF 70/354 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.117); catalogued as rs754587473, COSV65778772; called by muse, varscan2
- ANKRD27 | c.757G>T p.D253Y | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs138767777; called by muse, mutect2, varscan2
- ANKRD30B | c.1721C>A p.S574Y | Missense Mutation (SNP) | VAF 164/908 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.452); catalogued as COSV100746798, COSV62824700; called by muse, mutect2, varscan2
- ANKRD36 | c.195A>G p.E65= | Splice Region (SNP) | VAF 26/330 reads (8%) | catalogued as COSV101347560; called by muse, mutect2
- ANKRD45 | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 59/166 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs372141282; called by muse, mutect2, varscan2
- ANKRD50 | c.3568T>G p.S1190A | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.931); catalogued as COSV72386375; called by muse, mutect2, varscan2
- ANKRD52 | c.2409T>G p.H803Q | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.972); catalogued as COSV57287810; called by muse, mutect2, varscan2
- ANKRD61 | c.320C>T p.T107M | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.338); catalogued as rs771412351; called by muse, mutect2, varscan2
- ANKRD61 | c.1079G>A p.R360H | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs955471577; called by muse, mutect2
- ANKRD65 | c.1008G>T p.K336N | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as rs1326718445, COSV101408932; called by muse, mutect2, varscan2
- ANKS1B | c.2735C>T p.S912L (on ENST00000547776 / NM_152788.4; = p.S138L on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/280 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60357807; called by muse, mutect2, varscan2
- ANKZF1 | c.2088A>C p.Q696H | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV55479315; called by muse, mutect2, varscan2
- ANLN | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs767615862, COSV56074340; called by muse, mutect2, varscan2
- ANTXR2 | c.390A>C p.Q130H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55021434; called by muse, mutect2, varscan2
- ANXA2 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 58/385 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV60318953; called by muse, mutect2, varscan2
- AOC3 | c.1325G>A p.R442Q | Missense Mutation (SNP) | VAF 46/289 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757517219; called by muse, mutect2, varscan2
- AOPEP | c.2398G>A p.E800K (on ENST00000375315 / NM_001193329.1; = p.E701K on NM_032823.5) | Missense Mutation (SNP) | VAF 63/260 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.073); catalogued as rs559653559, COSV53000019; called by muse, mutect2, varscan2
- AP1G1 | c.296T>C p.V99A | Missense Mutation (SNP) | VAF 77/406 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.029); catalogued as rs745889361, COSV55495894; called by muse, mutect2, varscan2
- AP1M1 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.089); catalogued as rs1218074745, COSV52228789; called by muse, mutect2, varscan2
- AP2B1 | c.1706C>A p.S569Y | Missense Mutation (SNP) | VAF 24/440 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV99251774; called by muse, mutect2
- AP4E1 | c.3090C>A p.F1030L | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55920569; called by muse, mutect2, varscan2
- APAF1 | c.1539A>C p.K513N (on ENST00000551964 / NM_181861.2; = p.K502N on NM_001160.3) | Missense Mutation (SNP) | VAF 58/257 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59669009; called by muse, mutect2, varscan2
- APBB1 | c.943G>T p.E315* | Nonsense Mutation (SNP) | VAF 37/103 reads (36%) | catalogued as COSV54974409; called by muse, mutect2, varscan2
- APBB1IP | c.534C>T p.L178= | Splice Region (SNP) | VAF 26/91 reads (29%) | catalogued as rs143340134; called by muse, mutect2, varscan2
- APBB1IP | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66136749; called by muse, mutect2, varscan2
- APC | c.3842C>A p.S1281* | Nonsense Mutation (SNP) | VAF 38/145 reads (26%) | catalogued as CM106371, COSV57326196, COSV57330499; called by muse, mutect2, varscan2
- APC | c.6575A>C p.K2192T | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV57386832; called by muse, mutect2, varscan2
- APC | c.8401C>T p.R2801W | Missense Mutation (SNP) | VAF 20/288 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1242407699, COSV99970654; ClinVar: uncertain significance; called by muse, mutect2
- APOB | c.9450C>A p.F3150L | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as COSV51950504; called by muse, varscan2
- APOB | c.8297C>A p.S2766Y | Missense Mutation (SNP) | VAF 32/208 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV51954977; called by muse, mutect2, varscan2
- APOB | c.4400C>T p.A1467V | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as COSV51955005; called by muse, varscan2
- APOB | c.1284G>T p.E428D | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); catalogued as COSV51955038; called by muse, mutect2, varscan2
- APOBEC3G | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1011553055, COSV68469998; called by muse, mutect2
- APPBP2 | c.1552C>T p.R518* | Nonsense Mutation (SNP) | VAF 25/144 reads (17%) | catalogued as COSV50030105; called by muse, mutect2, varscan2
- APPL1 | c.971A>G p.D324G | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs746072561, COSV55703838; called by muse, mutect2, varscan2
- ARAP3 | c.2036A>G p.Y679C | Missense Mutation (SNP) | VAF 35/201 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV53355321; called by muse, mutect2, varscan2
- ARFGAP1 | c.751G>A p.V251I | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as rs147317838; called by mutect2, varscan2
- ARFGAP3 | c.1100C>A p.S367Y | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0.413); catalogued as COSV54314814; called by muse, mutect2, varscan2
- ARFGEF1 | c.3757C>T p.R1253* | Nonsense Mutation (SNP) | VAF 9/50 reads (18%) | catalogued as COSV51604329; called by muse, mutect2
- ARFGEF2 | c.3550C>A p.L1184M | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64215569; called by muse, mutect2, varscan2
- ARFIP1 | c.811C>T p.R271C (on ENST00000353617 / NM_001287432.1; = p.R239C on NM_014447.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776711621, COSV61886462; called by muse, mutect2, varscan2
- ARG2 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1566803283, COSV55777318; called by muse, mutect2, varscan2
- ARHGAP11A | c.522C>A p.F174L | Missense Mutation (SNP) | VAF 34/840 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV100853377; called by muse, mutect2
- ARHGAP12 | c.1884A>C p.K628N | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV60966707; called by muse, mutect2, varscan2
- ARHGAP17 | c.54-1G>T p.X18_splice | Splice Site (SNP) | VAF 55/308 reads (18%) | catalogued as COSV51506749, COSV99254153; called by muse, mutect2, varscan2
- ARHGAP20 | c.2598G>T p.K866N | Missense Mutation (SNP) | VAF 98/472 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.432); catalogued as COSV52820030; called by muse, mutect2, varscan2
- ARHGAP20 | c.1315C>T p.R439* | Nonsense Mutation (SNP) | VAF 39/208 reads (19%) | catalogued as rs751094122, COSV52808873; called by muse, mutect2, varscan2
- ARHGAP20 | c.1193T>C p.F398S | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52820049; called by muse, mutect2, varscan2
- ARHGAP24 | c.54G>T p.Q18H | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV67846187; called by muse, mutect2, varscan2
- ARHGAP32 | c.3757G>A p.E1253K (on ENST00000310343 / NM_001378025.1; = p.E904K on NM_014715.4) | Missense Mutation (SNP) | VAF 63/310 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.174); catalogued as rs768865360, COSV59847417; called by muse, varscan2
- ARHGAP35 | c.578A>C p.K193T | Missense Mutation (SNP) | VAF 59/259 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68336077; called by muse, mutect2, varscan2
- ARHGAP36 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs777932916, COSV52272714; called by muse, mutect2, varscan2
- ARHGAP40 | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 69/349 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1198366801; called by muse, mutect2, varscan2
- ARHGEF12 | c.2437T>C p.F813L | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63107615; called by muse, mutect2
- ARHGEF15 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1362528188, COSV62726799; called by muse, mutect2, varscan2
- ARHGEF18 | c.916G>T p.E306* (on ENST00000359920 / NM_001130955.2; = p.E202* on NM_015318.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 92/501 reads (18%) | catalogued as COSV60472156; called by muse, mutect2, varscan2
- ARHGEF26 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as rs903936492, COSV100726371, COSV62846065; called by muse, varscan2
- ARHGEF26 | c.1567G>A p.A523T | Missense Mutation (SNP) | VAF 69/306 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs757436159; called by muse, mutect2, varscan2
- ARHGEF26 | c.2107G>A p.V703I | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs571135932, COSV62852509; called by muse, mutect2, varscan2
- ARHGEF4 | c.335C>A p.S112Y | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.135); catalogued as COSV58131016; called by muse, mutect2, varscan2
- ARHGEF5 | c.1146G>T p.W382C | Missense Mutation (SNP) | VAF 56/363 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV99283261; called by mutect2, varscan2
- ARID2 | c.541A>G p.T181A | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV57615816; called by muse, mutect2, varscan2
- ARID3B | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 62/293 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.036); catalogued as COSV60559310; called by muse, mutect2, varscan2
- ARID4B | c.3063T>G p.N1021K | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV51611989; called by muse, mutect2, varscan2
- ARMC3 | c.715A>C p.K239Q | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.886); catalogued as COSV53068485; called by muse, mutect2, varscan2
- ARMC4 | c.706C>T p.R236* | Nonsense Mutation (SNP) | VAF 9/108 reads (8%) | catalogued as rs1279559573, COSV53467729; called by muse, mutect2
- ARMCX5 | c.692T>C p.V231A | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.981); catalogued as COSV55767765; called by muse, mutect2, varscan2
- ARMH3 | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 51/190 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.011); catalogued as COSV64238487; called by muse, mutect2, varscan2
- ARMT1 | c.1029T>A p.C343* | Nonsense Mutation (SNP) | VAF 30/127 reads (24%) | catalogued as COSV66179163; called by muse, mutect2, varscan2
- ARNTL | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs949259189, COSV62988189; called by muse, mutect2, varscan2
- ARPP21 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as rs535145550, COSV51792286, COSV51800995; called by muse, mutect2, varscan2
- ARSG | c.391G>A p.V131I | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs778128173, COSV71593687; called by muse, mutect2, varscan2
- ART4 | c.475T>G p.L159V | Missense Mutation (SNP) | VAF 45/249 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV57453422; called by muse, mutect2, varscan2
- ART5 | c.809T>C p.V270A | Missense Mutation (SNP) | VAF 46/196 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1363998968; called by muse, mutect2, varscan2
- ASAP1 | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.885); catalogued as rs759521913, COSV63046024; called by muse, mutect2, varscan2
- ASF1A | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 85/394 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57648147, COSV57648957; called by muse, mutect2, varscan2
- ASIC5 | c.1304C>T p.A435V | Missense Mutation (SNP) | VAF 111/576 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as rs142024528; called by muse, mutect2, varscan2
- ASMTL | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.945); catalogued as rs200707318, COSV101187745; called by muse, mutect2, varscan2
- ASPG | c.393G>T p.E131D | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV104437447; called by muse, mutect2, varscan2
- ASPM | c.8622A>C p.Q2874H | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.348); catalogued as COSV99661229; called by muse, mutect2
- ASPM | c.6412A>G p.T2138A | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs1372714173, COSV54139795; called by muse, mutect2, varscan2
- ASXL2 | c.711A>C p.K237N | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV55468765; called by muse, varscan2
- ASZ1 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99498360; called by muse, mutect2
- ATAD2 | c.3808T>C p.C1270R | Missense Mutation (SNP) | VAF 58/294 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs1185968057, COSV54887372; called by muse, mutect2, varscan2
- ATAD2 | c.637G>T p.E213* | Nonsense Mutation (SNP) | VAF 82/326 reads (25%) | catalogued as COSV54887386; called by muse, mutect2, varscan2
- ATF3 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 16/324 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.634); catalogued as rs1389773222; called by muse, mutect2
- ATF5 | c.281C>A p.T94N | Missense Mutation (SNP) | VAF 43/172 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs1165087321, COSV100352412, COSV61313627; called by muse, mutect2, varscan2
- ATF6 | c.503A>C p.K168T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV63410389; called by muse, mutect2
- ATG16L1 | c.1108A>G p.T370A (on ENST00000392017 / NM_030803.7; = p.T351A on NM_017974.4) | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV61468292, COSV61468423; called by muse, mutect2, varscan2
- ATG16L1 | c.1414C>T p.R472C (on ENST00000392017 / NM_030803.7; = p.R453C on NM_017974.4) | Missense Mutation (SNP) | VAF 53/201 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61468059; called by muse, mutect2, varscan2
- ATG2B | c.2428G>T p.E810* | Nonsense Mutation (SNP) | VAF 19/116 reads (16%) | catalogued as COSV63426033; called by muse, mutect2, varscan2
- ATG4C | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 20/90 reads (22%) | catalogued as COSV58608836; called by muse, mutect2, varscan2
- ATG4C | c.666G>T p.K222N | Missense Mutation (SNP) | VAF 45/239 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV58608849; called by muse, mutect2, varscan2
- ATIC | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 57/285 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as rs199518893, COSV52692257; called by muse, mutect2, varscan2
- ATM | c.1431G>T p.K477N | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV53778503; called by muse, mutect2, varscan2
- ATM | c.6229C>A p.L2077I | Missense Mutation (SNP) | VAF 42/202 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV53778521, COSV53783409; called by muse, mutect2, varscan2
- ATP10A | c.2579C>T p.A860V | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as rs1200926843, COSV63525602; called by muse, mutect2, varscan2
- ATP10D | c.2333G>T p.R778I | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99906258; called by muse, mutect2
- ATP11C | c.1838G>T p.R613I | Missense Mutation (SNP) | VAF 89/175 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs776753802, COSV59561860, COSV59563934; called by muse, mutect2, varscan2
- ATP11C | c.1378-1G>A p.X460_splice | Splice Site (SNP) | VAF 41/145 reads (28%) | catalogued as COSV100558754; called by muse, mutect2, varscan2
- ATP12A | c.2171A>G p.D724G | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54524194; called by muse, mutect2, varscan2
- ATP1A2 | c.1705G>A p.D569N | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as rs1409103763, COSV63405744; called by muse, mutect2, varscan2
- ATP1A4 | c.1663C>A p.L555M | Missense Mutation (SNP) | VAF 33/380 reads (9%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.62); catalogued as COSV100927655; called by muse, mutect2
- ATP2A1 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1217263743, COSV63920520; called by muse, mutect2, varscan2
- ATP2A2 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 93/304 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as COSV58048028; called by muse, mutect2, varscan2
- ATP2A2 | c.1855C>T p.R619W | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs1201260065, COSV57876442; called by muse, mutect2, varscan2
- ATP2B1 | c.3419C>T p.S1140L | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as COSV53803716; called by muse, mutect2
- ATP2B1 | c.3130T>C p.S1044P | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV53813659; called by muse, mutect2
- ATP2C1 | c.1672A>G p.T558A | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as COSV60763345; called by muse, mutect2, varscan2
- ATP5PB | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 70/328 reads (21%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs11553277, COSV71953300; called by muse, varscan2
- ATP6V0A4 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374791119, COSV59474220; called by muse, mutect2, varscan2
- ATP6V0C | c.50T>C p.M17T | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV100383535; called by mutect2, varscan2
- ATP6V0D2 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 13/155 reads (8%) | catalogued as COSV53416678, COSV53418240; called by muse, mutect2
- ATP6V1C2 | c.762G>T p.E254D | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.434); catalogued as rs747722346; called by muse, mutect2, varscan2
- ATP6V1E2 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as rs773871657, COSV60576722; called by muse, mutect2, varscan2
- ATP8A1 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 151/316 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372884316; called by muse, mutect2, varscan2
- ATP8A1 | c.241T>G p.F81V | Missense Mutation (SNP) | VAF 22/408 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100047473; called by muse, mutect2
- ATP8B3 | c.868G>T p.E290* | Nonsense Mutation (SNP) | VAF 41/195 reads (21%) | catalogued as COSV59544191; called by muse, mutect2, varscan2
- ATP8B4 | c.2663T>G p.F888C | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as COSV52725554; called by muse, mutect2, varscan2
- ATP8B4 | c.1524C>A p.F508L | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52725563; called by muse, mutect2, varscan2
- ATP8B4 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 45/261 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs945620225, COSV52724140; called by muse, mutect2, varscan2
- ATRN | c.1547T>C p.V516A | Missense Mutation (SNP) | VAF 24/346 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as COSV99497924; called by muse, mutect2
- ATRX | c.7157G>A p.R2386Q | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV100971556; called by muse, mutect2, varscan2
- ATRX | c.6666G>T p.K2222N | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.313); catalogued as COSV100971550, COSV100971557; called by muse, mutect2
- ATXN2L | c.313G>T p.G105* | Nonsense Mutation (SNP) | VAF 18/103 reads (17%) | catalogued as COSV57379874; called by muse, mutect2, varscan2
- AUTS2 | c.859G>T p.E287* | Nonsense Mutation (SNP) | VAF 42/142 reads (30%) | catalogued as COSV61432380; called by muse, mutect2, varscan2
- AWAT2 | c.64T>C p.S22P | Missense Mutation (SNP) | VAF 89/216 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV52144750; called by muse, mutect2, varscan2
- AXDND1 | c.1165G>T p.D389Y | Missense Mutation (SNP) | VAF 101/512 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62639258, COSV62649423; called by muse, mutect2, varscan2
- AXDND1 | c.1997C>T p.S666L | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs766225252, COSV62639335; called by muse, mutect2, varscan2
- B3GALT2 | c.408C>A p.F136L | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as COSV66464589; called by muse, mutect2, varscan2
- B3GALT2 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as rs751156224, COSV66463997; called by muse, mutect2, varscan2
- B3GAT1 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as rs368413334; called by muse, mutect2, varscan2
- B3GAT2 | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.098); catalogued as COSV100017495; called by muse, mutect2, varscan2
- B3GNT2 | c.157A>G p.T53A | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs777061198, COSV57345700; called by muse, mutect2, varscan2
- B4GALT5 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.34); catalogued as rs369508203; called by muse, mutect2, varscan2
- BAALC | c.305G>A p.R102Q (on ENST00000297574 / NM_001364874.1; = p.R67Q on NM_024812.3) | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.478); catalogued as rs200984161; called by muse, mutect2, varscan2
- BAALC | c.528G>T p.K176N (on ENST00000297574 / NM_001364874.1; = p.K141N on NM_024812.3) | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as COSV52565409; called by muse, mutect2
- BACE1 | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs138644093; called by muse, mutect2, varscan2
- BANP | c.1491G>A p.T497= (on ENST00000286122; = p.T447= on NM_017869.4) | Splice Region (SNP) | VAF 15/103 reads (15%) | catalogued as rs1022129832, COSV99622496; called by muse, mutect2, varscan2
- BAZ1A | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs527680155, COSV62412314; called by muse, mutect2, varscan2
- BAZ1B | c.842A>C p.K281T | Missense Mutation (SNP) | VAF 46/243 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV59994934; called by muse, mutect2, varscan2
- BAZ1B | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 68/368 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs1554575752, COSV59989118; called by muse, mutect2, varscan2
- BAZ2A | c.3227T>C p.V1076A | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as rs775845435, COSV51644645; called by muse, mutect2, varscan2
- BBS2 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.476); catalogued as rs150572808; called by muse, varscan2
- BBX | c.1117T>G p.F373V | Missense Mutation (SNP) | VAF 42/205 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1381702570, COSV57895934; called by muse, mutect2, varscan2
- BCL2L13 | c.219A>C p.E73D | Missense Mutation (SNP) | VAF 71/280 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as rs568678964, COSV58227913; called by muse, mutect2, varscan2
- BCL6 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.048); catalogued as rs780987785, COSV51653974; called by muse, mutect2, varscan2
- BCL9 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs782706803, COSV52350740; called by muse, mutect2
- BCLAF1 | c.1093G>T p.G365* | Nonsense Mutation (SNP) | VAF 9/41 reads (22%) | catalogued as COSV62146254; called by muse, mutect2, varscan2
- BEND4 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.797); catalogued as COSV101549806; called by muse, mutect2
- BEST2 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.108); catalogued as COSV50378941; called by muse, mutect2, varscan2
- BFSP2 | c.1027C>T p.R343* | Nonsense Mutation (SNP) | VAF 14/45 reads (31%) | catalogued as rs767599025, COSV56593012; called by muse, mutect2, varscan2
- BHLHE23 | c.416C>T p.S139F (on ENST00000370346; = p.S155F on NM_080606.4) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100947632; called by muse, mutect2, varscan2
- BICD2 | c.1531G>A p.D511N | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.688); catalogued as COSV63551158; called by muse, mutect2, varscan2
- BICD2 | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.883); catalogued as rs761506224, COSV63551166; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BICRAL | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 55/273 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.927); catalogued as rs780885776, COSV58408739; called by muse, mutect2, varscan2
- BIRC6 | c.12277G>T p.E4093* | Nonsense Mutation (SNP) | VAF 20/107 reads (19%) | catalogued as COSV66042998; called by muse, mutect2, varscan2
- BIRC6 | c.14174G>A p.R4725Q | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.761); catalogued as COSV70198010; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1271G>T p.R424I | Missense Mutation (SNP) | VAF 33/255 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV57279584; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1573C>T p.R525C | Missense Mutation (SNP) | VAF 61/236 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1400329743, COSV63244190, COSV63244592; called by muse, varscan2
- BIVM-ERCC5 | c.1990G>T p.E664* | Nonsense Mutation (SNP) | VAF 31/153 reads (20%) | catalogued as COSV63247633; called by muse, mutect2, varscan2
- BLM | c.3431G>T p.R1144I | Missense Mutation (SNP) | VAF 60/325 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as COSV61927820; called by muse, mutect2, varscan2
- BMP6 | c.1227A>C p.K409N | Missense Mutation (SNP) | VAF 65/209 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV51672929; called by muse, mutect2, varscan2
- BMP7 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as rs772689429; called by muse, mutect2, varscan2
- BMPER | c.1607G>A p.R536K | Missense Mutation (SNP) | VAF 48/194 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV51832711; called by muse, mutect2, varscan2
- BMPR1B | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV52782410; called by muse, mutect2, varscan2
- BMPR1B | c.1087G>T p.E363* | Nonsense Mutation (SNP) | VAF 28/131 reads (21%) | catalogued as COSV52782425; called by muse, varscan2
- BMPR1B | c.1166G>T p.R389I | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.534); catalogued as COSV52782447; called by muse, varscan2
- BMPR2 | c.2510A>G p.N837S | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV65813796; called by muse, mutect2, varscan2
- BNC1 | c.2078C>T p.A693V | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as rs146647716; called by muse, mutect2, varscan2
- BNC1 | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs759909793, COSV100597453; called by muse, mutect2, varscan2
- BNC2 | c.1534C>T p.R512W | Missense Mutation (SNP) | VAF 50/215 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773045476, COSV66142375; called by muse, mutect2, varscan2
- BNIP5 | c.482A>G p.H161R | Missense Mutation (SNP) | VAF 95/481 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.445); catalogued as COSV71325882; called by muse, mutect2, varscan2
- BPIFB1 | c.577C>A p.P193T | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53609060; called by muse, mutect2, varscan2
- BPTF | c.5876G>A p.R1959Q | Missense Mutation (SNP) | VAF 55/247 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs556375365, COSV58848081; called by muse, mutect2, varscan2
- BRCA2 | c.996T>G p.I332M | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.89); catalogued as COSV66463357; called by muse, mutect2, varscan2
- BRCA2 | c.6473T>G p.F2158C | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV66463360; called by muse, mutect2, varscan2
- BRCA2 | c.9253A>G p.T3085A | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as CD121947, COSV66454758, COSV66463364; called by muse, mutect2, varscan2
- BRD9 | c.1705C>T p.R569C | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.245); catalogued as rs758871899, COSV100057545, COSV60248464; called by muse, mutect2, varscan2
- BRINP3 | c.1600C>T p.L534F | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV66524657; called by muse, mutect2, varscan2
- BRIP1 | c.1871C>T p.S624L | Missense Mutation (SNP) | VAF 43/271 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587781321, CM1411623, COSV51998688; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRWD1 | c.3007G>T p.E1003* | Nonsense Mutation (SNP) | VAF 27/99 reads (27%) | catalogued as COSV60903539; called by muse, mutect2, varscan2
- BRWD1 | c.305C>A p.S102Y | Missense Mutation (SNP) | VAF 98/430 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV58122834; called by muse, mutect2, varscan2
- BSN | c.1289C>T p.P430L | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs778102168, COSV56528852; called by muse, mutect2, varscan2
- BSN | c.7096C>T p.R2366W | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs752861640, COSV99610012; called by muse, mutect2, varscan2
- BTAF1 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200229615, COSV56436282; called by muse, varscan2
- BTAF1 | c.3722G>A p.R1241Q | Missense Mutation (SNP) | VAF 104/404 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as rs762217759, COSV56440051; called by muse, mutect2, varscan2
- BTBD11 | c.104C>A p.S35Y | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV99777132; called by muse, mutect2, varscan2
- BTBD3 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as COSV54780819; called by muse, mutect2, varscan2
- BTBD8 | c.4054C>T p.R1352* (on ENST00000636805 / NM_001376131.1; = p.R839* on NM_015237.4) | Nonsense Mutation (SNP) | VAF 29/105 reads (28%) | catalogued as rs1282439973; called by muse, mutect2, varscan2
- BTF3L4 | c.372C>A p.V124= | Splice Region (SNP) | VAF 14/224 reads (6%) | catalogued as COSV100511269; called by muse, mutect2
- BTK | c.1001A>G p.Y334C | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM940191, COSV58124056; called by muse, mutect2, varscan2
- BTK | c.152G>A p.S51N | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as COSV58124080; called by muse, mutect2, varscan2
- BTK | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs368549990, COSV58117893, COSV58121329; called by muse, mutect2
- BTN3A3 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 47/223 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1348988194, COSV55073989; called by muse, mutect2, varscan2
- BUB1 | c.1310C>A p.S437Y | Missense Mutation (SNP) | VAF 69/250 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV57061159; called by muse, mutect2, varscan2
- BUD13 | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs753401362, COSV52770718; called by muse, mutect2, varscan2
- C10orf67 | c.1564C>T p.P522S | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.007); catalogued as rs1250013366; called by muse, mutect2, varscan2
- C11orf53 | c.793C>T p.H265Y | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.708); catalogued as COSV54721084, COSV54722562; called by muse, mutect2, varscan2
- C12orf40 | c.659T>C p.F220S | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV61138217; called by muse, varscan2
- C12orf42 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.25); catalogued as rs374331136; called by muse, varscan2
- C12orf50 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 10/68 reads (15%) | catalogued as COSV100072373; called by muse, varscan2
- C14orf28 | c.186C>A p.F62L | Missense Mutation (SNP) | VAF 58/219 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV57332835, COSV57334153; called by muse, mutect2, varscan2
- C16orf46 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 108/604 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV55153523; called by muse, mutect2, varscan2
- C19orf18 | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs146255633, COSV58705690; called by mutect2, varscan2
- C1GALT1C1 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 66/154 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV58973706; called by muse, mutect2, varscan2
- C1QL2 | c.860A>G p.D287G | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99733388; called by muse, mutect2, varscan2
- C1QTNF1 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs767734960, COSV59262440; called by muse, mutect2, varscan2
- C1orf100 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs906645188, COSV57374449; called by muse, mutect2, varscan2
- C1orf112 | c.332C>A p.S111Y | Missense Mutation (SNP) | VAF 51/309 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.934); catalogued as COSV53683241; called by muse, varscan2
- C20orf203 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 78/232 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.691); catalogued as rs1379168007, COSV100667984; called by muse, mutect2, varscan2
- C2CD4C | c.491C>A p.S164Y | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100173774; called by muse, mutect2, varscan2
- C2orf66 | c.74G>T p.R25I | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV61099280; called by muse, mutect2, varscan2
- C3AR1 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs56297048, COSV50820555; called by muse, mutect2, varscan2
- C5 | c.5003C>T p.A1668V | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs765573116, COSV56332579; called by muse, mutect2, varscan2
- C5 | c.4432C>T p.R1478W | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs138933092; called by muse, mutect2, varscan2
- C5 | c.1229T>C p.V410A | Missense Mutation (SNP) | VAF 129/553 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0.015); catalogued as COSV56332594; called by muse, mutect2, varscan2
- C5 | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 65/314 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs544818019, COSV56326412; called by muse, varscan2
- C7 | c.1765T>C p.F589L | Missense Mutation (SNP) | VAF 78/330 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV57473442; called by muse, mutect2, varscan2
- C7orf25 | c.83G>T p.R28I | Missense Mutation (SNP) | VAF 71/249 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.276); catalogued as COSV63274424; called by muse, mutect2, varscan2
- C8orf48 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 12/211 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1472627562, COSV99813558; called by muse, mutect2
- C9orf131 | c.1100A>G p.D367G | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.272); catalogued as COSV56614586; called by muse, mutect2, varscan2
- C9orf43 | c.707A>C p.K236T | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV99928650; called by muse, mutect2, varscan2
- CABP2 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 49/339 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as rs777036556, COSV99590819; called by muse, mutect2, varscan2
- CABP7 | c.111G>A p.E37= | Splice Region (SNP) | VAF 13/63 reads (21%) | catalogued as COSV99334947; called by muse, mutect2, varscan2
- CACHD1 | c.1082C>A p.T361N | Missense Mutation (SNP) | VAF 58/251 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV51560641; called by muse, mutect2, varscan2
- CACNA1A | c.5785C>T p.R1929W | Missense Mutation (SNP) | VAF 15/286 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100803349; called by muse, mutect2
- CACNA1A | c.485G>A p.G162D | Missense Mutation (SNP) | VAF 84/276 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as CM163640, COSV64213842; called by muse, varscan2
- CACNA1B | c.5233A>C p.S1745R | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.33); catalogued as COSV53121841, COSV53151232; called by muse, mutect2, varscan2
- CACNA1B | c.6170A>C p.H2057P | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.959); catalogued as COSV99500240; called by muse, mutect2, varscan2
- CACNA1C | c.1945C>T p.R649C | Missense Mutation (SNP) | VAF 62/241 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs769236083, COSV59710215; called by muse, varscan2
- CACNA1C | c.2129C>T p.S710L | Missense Mutation (SNP) | VAF 82/319 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV59695046; called by muse, mutect2, varscan2
- CACNA1C | c.2504G>A p.S835N | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV59778068; called by muse, mutect2, varscan2
- CACNA1E | c.3945C>A p.F1315L | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV62431308; called by muse, mutect2, varscan2
- CACNA1E | c.6095C>T p.S2032L (on ENST00000367573 / NM_001205293.3; = p.S1989L on NM_000721.4) | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0.015); catalogued as rs1049589906, COSV62395266; called by muse, mutect2, varscan2
- CACNA1H | c.3840G>T p.Q1280H | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.122); catalogued as COSV100673620; called by muse, mutect2, varscan2
- CACNA1I | c.3403G>A p.D1135N | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as rs768117821; called by muse, mutect2, varscan2
- CACNB1 | c.712T>C p.S238P | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60000537; called by muse, mutect2, varscan2
- CADM2 | c.525G>T p.E175D (on ENST00000407528 / NM_001167674.2; = p.E177D on NM_153184.4) | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.129); catalogued as COSV67407777; called by muse, mutect2, varscan2
- CADM3 | c.901G>T p.A301S (on ENST00000368125 / NM_001127173.3; = p.A335S on NM_021189.5) | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63687668; called by muse, mutect2, varscan2
- CADPS | c.1287G>T p.E429D | Missense Mutation (SNP) | VAF 68/382 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as COSV51905887; called by muse, mutect2, varscan2
- CADPS | c.926G>A p.R309Q | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51905907; called by muse, mutect2, varscan2
- CADPS | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as COSV51905924; called by muse, mutect2, varscan2
- CALCB | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 17/373 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV100158142; called by muse, mutect2
- CALCR | c.1242C>A p.V414= (on ENST00000649521 / NM_001164737.2; = p.V398= on NM_001742.4) | Splice Region (SNP) | VAF 18/111 reads (16%) | catalogued as COSV100810916, COSV64012461; called by muse, mutect2, varscan2
- CALD1 | c.1994C>T p.S665L (on ENST00000361675 / NM_033138.4; = p.S410L on NM_004342.7) | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.159); catalogued as rs1372249532, COSV62654897; called by muse, mutect2, varscan2
- CAMK1 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs746723292, COSV56540563; called by muse, mutect2, varscan2
- CAMKV | c.447G>T p.E149D | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56558081; called by muse, mutect2, varscan2
- CAND1 | c.2203C>A p.L735I | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV73389799; called by muse, mutect2, varscan2
- CAND2 | c.2717C>T p.A906V (on ENST00000456430 / NM_001162499.2; = p.A813V on NM_012298.3) | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV99929925; called by muse, mutect2
- CAPN13 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 41/225 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.326); catalogued as rs542792832, COSV54429633; called by muse, mutect2, varscan2
- CAPN14 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs780854483; called by muse, mutect2, varscan2
- CAPN5 | c.739G>A p.D247N (on ENST00000456580; = p.D207N on NM_004055.5) | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.231); catalogued as rs367724731, COSV53687605; called by muse, mutect2, varscan2
- CAPN7 | c.390A>C p.K130N | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as COSV53781035; called by muse, mutect2, varscan2
- CAPN8 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.863); catalogued as rs868835035, COSV64817694; called by muse, varscan2
- CAPNS2 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766790678, COSV50900476; called by muse, mutect2, varscan2
- CAPRIN2 | c.2185G>T p.E729* | Nonsense Mutation (SNP) | VAF 86/402 reads (21%) | catalogued as COSV51834002; called by muse, varscan2
- CAPSL | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs199837654; called by muse, mutect2, varscan2
- CARMIL1 | c.3193C>T p.R1065W | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs753444416, COSV61524570; called by muse, mutect2, varscan2
- CARNS1 | c.2116C>T p.L706F | Missense Mutation (SNP) | VAF 73/397 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV100322262; called by muse, mutect2, varscan2
- CASK | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 107/297 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.123); catalogued as COSV59376251; called by muse, mutect2, varscan2
- CASP5 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as rs543265797, COSV52829825; called by muse, mutect2
- CASP8AP2 | c.3860G>A p.R1287Q | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.635); catalogued as rs375610839; called by muse, mutect2, varscan2
- CATSPERB | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 13/99 reads (13%) | catalogued as rs779893104, COSV56422429, COSV99831126; called by muse, mutect2
- CAVIN3 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs1028188353, COSV58268780; called by muse, mutect2
- CAVIN4 | c.390C>A p.F130L | Missense Mutation (SNP) | VAF 46/207 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56868488; called by muse, mutect2, varscan2
- CBFB | c.542G>T p.R181I | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.695); catalogued as COSV52001997; called by muse, mutect2, varscan2
- CBLB | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 16/78 reads (21%) | catalogued as rs1476526903, COSV51430548; called by muse, mutect2
- CBR4 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 57/291 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV60371038; called by muse, mutect2, varscan2
- CC2D2B | c.103C>A p.L35I | Missense Mutation (SNP) | VAF 12/167 reads (7%) | SIFT tolerated (0.85); PolyPhen benign (0.155); catalogued as COSV100729587; called by muse, mutect2
- CCBE1 | c.464G>A p.G155D | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV67951716; called by muse, mutect2, varscan2
- CCDC105 | c.623G>A p.S208N | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.19); catalogued as COSV52963221, COSV52965823; called by muse, mutect2, varscan2
- CCDC112 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); catalogued as COSV65474076; called by muse, mutect2, varscan2
- CCDC116 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141137219; called by muse, mutect2, varscan2
- CCDC136 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 49/185 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV52805903; called by muse, mutect2, varscan2
- CCDC14 | c.1795A>G p.T599A (on ENST00000488653; = p.T551A on NM_022757.5) | Missense Mutation (SNP) | VAF 67/288 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV59948222; called by muse, mutect2, varscan2
- CCDC141 | c.3796C>A p.L1266I | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.073); catalogued as COSV55383368; called by muse, mutect2, varscan2
- CCDC141 | c.2206-1G>A p.X736_splice | Splice Site (SNP) | VAF 26/98 reads (27%) | catalogued as COSV99837606; called by muse, varscan2
- CCDC144A | c.1390A>C p.N464H | Missense Mutation (SNP) | VAF 89/1453 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.348); catalogued as COSV100138730; called by muse, mutect2
- CCDC144A | c.3791C>T p.S1264L | Missense Mutation (SNP) | VAF 143/505 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as rs777407520, COSV60697225, COSV60699146; called by mutect2, varscan2
- CCDC149 | c.386C>T p.T129M | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1190356614, COSV60882467; called by muse, varscan2
- CCDC157 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs750607091; called by muse, mutect2, varscan2
- CCDC168 | c.21170C>T p.S7057F | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV100487592, COSV100488088, COSV59422815; called by muse, mutect2, varscan2
- CCDC168 | c.16754G>A p.R5585Q | Missense Mutation (SNP) | VAF 49/186 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs760443346, COSV59421301; called by muse, mutect2, varscan2
- CCDC168 | c.14150G>A p.R4717Q | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.294); catalogued as rs1024842352, COSV100487598; called by muse, mutect2, varscan2
- CCDC168 | c.13988T>C p.I4663T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs1249979033; called by muse, mutect2, varscan2
- CCDC168 | c.10727C>T p.S3576L | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs765838371, COSV59421777; called by muse, mutect2, varscan2
- CCDC168 | c.9337G>A p.E3113K | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.121); catalogued as rs761797818, COSV59422520; called by muse, mutect2, varscan2
- CCDC168 | c.3104C>T p.T1035M | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs189997066, COSV70554817; called by mutect2, varscan2
- CCDC17 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as COSV99322804; called by muse, mutect2
- CCDC170 | c.444-1G>A p.X148_splice | Splice Site (SNP) | VAF 10/104 reads (10%) | catalogued as COSV53344345, COSV53347724; called by muse, mutect2
- CCDC170 | c.1931A>C p.E644A | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT tolerated (0.78); PolyPhen benign (0.012); catalogued as COSV53347007; called by muse, mutect2, varscan2
- CCDC174 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 37/180 reads (21%) | catalogued as COSV57980621, COSV99070631; called by muse, varscan2
- CCDC178 | c.2317G>T p.E773* (on ENST00000383096 / NM_001105528.3; = p.E735* on NM_198995.3) | Nonsense Mutation (SNP) | VAF 37/151 reads (25%) | catalogued as rs150180566; called by muse, varscan2
- CCDC22 | c.1343G>A p.R448Q | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.95); catalogued as rs782344227, COSV66051643; called by muse, mutect2
- CCDC25 | c.157C>T p.R53* | Nonsense Mutation (SNP) | VAF 60/163 reads (37%) | catalogued as rs747557723, COSV62958328; called by muse, mutect2, varscan2
- CCDC27 | c.1653G>T p.K551N | Missense Mutation (SNP) | VAF 48/214 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs1163540191; called by muse, mutect2, varscan2
- CCDC30 | c.1397C>T p.T466I (on ENST00000340612; = p.T423I on NM_001080850.3) | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.042); catalogued as COSV59609735; called by muse, mutect2, varscan2
- CCDC39 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 76/236 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1458123630, COSV56483732; called by muse, mutect2, varscan2
- CCDC51 | c.603G>T p.K201N | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56494657; called by muse, mutect2, varscan2
- CCDC65 | c.420A>C p.E140D | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV57198195; called by muse, mutect2, varscan2
- CCDC73 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 110/652 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58799590; called by muse, varscan2
- CCDC80 | c.1288A>G p.T430A | Missense Mutation (SNP) | VAF 21/394 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV99245399; called by muse, mutect2
- CCDC91 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 35/214 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.294); catalogued as rs753292484, COSV60339547; called by muse, mutect2, varscan2
- CCDC92 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 19/265 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs777304210, COSV99435221; called by muse, mutect2
- CCDC93 | c.1350+1G>A p.X450_splice | Splice Site (SNP) | VAF 17/93 reads (18%) | catalogued as rs140512719, COSV60119915; called by muse, mutect2, varscan2
- CCER1 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as COSV100727100, COSV62647956; called by muse, mutect2
- CCHCR1 | c.1462C>T p.R488C | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1173895969; called by muse, mutect2, varscan2
- CCHCR1 | c.547A>G p.T183A | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.415); catalogued as COSV66185222; called by muse, mutect2, varscan2
- CCKBR | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.056); catalogued as COSV58099436, COSV58107007; called by muse, mutect2, varscan2
- CCKBR | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58104557; called by muse, varscan2
- CCL14 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 127/242 reads (52%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs771441014; called by muse, mutect2, varscan2
- CCN6 | c.761G>A p.S254N | Missense Mutation (SNP) | VAF 22/338 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100037228; called by muse, mutect2
- CCNB2 | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV55596779; called by muse, mutect2, varscan2
- CCNY | c.362A>C p.K121T | Missense Mutation (SNP) | VAF 63/249 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV55191629; called by muse, mutect2, varscan2
- CCR1 | c.785C>A p.S262Y | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.183); catalogued as rs1166195742, COSV56122205; called by muse, mutect2, varscan2
- CCR2 | c.944T>G p.L315R | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV99432615; called by muse, mutect2, varscan2
- CCR8 | c.364T>C p.F122L | Missense Mutation (SNP) | VAF 118/424 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as COSV58337376; called by muse, mutect2, varscan2
- CCT3 | c.59G>T p.R20I | Missense Mutation (SNP) | VAF 16/312 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV55291345; called by muse, mutect2
- CD109 | c.3515G>T p.R1172I | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54656998, COSV99754797; called by muse, mutect2
- CD163 | c.3302C>A p.S1101Y | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.896); catalogued as rs1250219603, COSV63134475, COSV63137975; called by muse, mutect2, varscan2
- CD163 | c.3008C>A p.S1003Y | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV63131592, COSV63137983; called by muse, mutect2, varscan2
- CD1E | c.993dup p.Q332Tfs*5 | Frame Shift Ins (INS) | VAF 48/322 reads (15%) | catalogued as rs866136574; called by mutect2, varscan2
- CD2 | c.141T>G p.S47R | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV65643778; called by muse, mutect2, varscan2
- CD226 | c.438G>T p.K146N | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV54614674, COSV54616504, COSV99710753; called by muse, mutect2
- CD244 | c.385C>A p.L129M | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV59241989; called by muse, mutect2, varscan2
- CD3D | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 33/150 reads (22%) | catalogued as rs777721098, COSV56140079; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD3G | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.804); catalogued as rs201752677, COSV99416902; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD70 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs182050995, COSV55565917; called by muse, mutect2, varscan2
- CD72 | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 62/333 reads (19%) | catalogued as COSV52411772; called by muse, mutect2, varscan2
- CD93 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.041); catalogued as rs757350790, COSV99849270; called by muse, varscan2
- CD99L2 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.7); PolyPhen benign (0.024); catalogued as rs146802752, COSV60938757; called by muse, mutect2, varscan2
- CDC16 | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 75/340 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as COSV52958807; called by muse, mutect2, varscan2
- CDC16 | c.1685C>T p.P562L | Missense Mutation (SNP) | VAF 44/241 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as rs1272008863, COSV52962117; called by muse, mutect2, varscan2
- CDC23 | c.1239G>T p.K413N | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.14); catalogued as COSV101203113, COSV67510739; called by muse, mutect2, varscan2
- CDC42BPA | c.2085G>T p.K695N | Missense Mutation (SNP) | VAF 13/182 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.566); catalogued as COSV100506730; called by muse, mutect2
- CDC42BPA | c.143G>A p.R48K | Missense Mutation (SNP) | VAF 41/198 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.092); catalogued as COSV62023249; called by muse, mutect2, varscan2
- CDC42BPB | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as rs772636121, COSV63477099; called by muse, mutect2, varscan2
- CDC73 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM072926, COSV66465222; called by muse, mutect2, varscan2
- CDCA7L | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770755131; called by muse, mutect2, varscan2
- CDCA8 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs187658080, COSV59238766; called by muse, mutect2, varscan2
- CDCP1 | c.2287C>T p.R763W | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs758096347, COSV56105850; called by muse, mutect2, varscan2
- CDH1 | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs876660645, COSV55730544, COSV55733510, COSV55735767; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH10 | c.1573T>G p.F525V | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.041); catalogued as COSV52600042; called by muse, mutect2
- CDH10 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.822); catalogued as rs138533676; called by muse, mutect2, varscan2
- CDH11 | c.395A>G p.D132G | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51778990; called by muse, mutect2, varscan2
- CDH17 | c.1679T>C p.V560A | Missense Mutation (SNP) | VAF 37/208 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760876203, COSV50343788; called by muse, mutect2, varscan2
- CDH18 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 112/481 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.401); catalogued as rs148450624, COSV56937399; called by muse, mutect2, varscan2
- CDH18 | c.517G>T p.D173Y | Missense Mutation (SNP) | VAF 48/226 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.489); catalogued as COSV56964761; called by muse, varscan2
- CDH18 | c.434T>G p.F145C | Missense Mutation (SNP) | VAF 87/365 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56964783; called by muse, mutect2, varscan2
- CDH19 | c.896A>G p.D299G | Missense Mutation (SNP) | VAF 47/216 reads (22%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as COSV50979948; called by muse, mutect2, varscan2
- CDH2 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 52/225 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV52297947; called by muse, mutect2, varscan2
- CDH20 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV53009145, COSV53014733; called by muse, mutect2, varscan2
- CDH3 | c.1621G>A p.V541I | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs868118578, COSV50577609; called by muse, mutect2, varscan2
- CDH8 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.037); catalogued as rs762249948, COSV54865707, COSV54878044; called by muse, mutect2, varscan2
- CDH8 | c.182G>T p.R61I | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99076732; called by muse, varscan2
- CDH9 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 61/126 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50415316; called by muse, mutect2, varscan2
- CDK17 | c.1510C>T p.R504* | Nonsense Mutation (SNP) | VAF 18/88 reads (20%) | catalogued as rs750936507, COSV54127953; called by muse, mutect2, varscan2
- CDK18 | c.31C>T p.R11C | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs748768587, COSV63729044; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4208G>A p.R1403Q | Missense Mutation (SNP) | VAF 45/222 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767034315, COSV62574308; called by muse, mutect2, varscan2
- CDON | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145492265, COSV54998134; called by muse, mutect2, varscan2
- CDRT15L2 | c.704G>A p.S235N | Missense Mutation (SNP) | VAF 59/215 reads (27%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.393); catalogued as rs1179977620; called by muse, mutect2, varscan2
- CEACAM18 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.024); catalogued as rs1220816040, COSV67284196; called by muse, mutect2, varscan2
- CEACAM21 | c.816C>A p.D272E (on ENST00000401445 / NM_001098506.4; = p.D271E on NM_033543.6) | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV51816894; called by muse, mutect2, varscan2
- CELF6 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 62/241 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs761929086, COSV54717292; called by muse, mutect2, varscan2
- CELSR3 | c.6550C>T p.R2184* | Nonsense Mutation (SNP) | VAF 10/70 reads (14%) | catalogued as rs777364198, COSV99375238; called by mutect2, varscan2
- CEMIP | c.2435G>A p.G812D | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55001034; called by muse, mutect2, varscan2
- CEMIP2 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV65489859; called by muse, mutect2
- CENPE | c.7952C>A p.S2651Y | Missense Mutation (SNP) | VAF 33/260 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54391695, COSV99478723; called by muse, mutect2, varscan2
- CENPF | c.716G>A p.R239K | Missense Mutation (SNP) | VAF 47/165 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); catalogued as COSV65279564; called by muse, mutect2, varscan2
- CENPF | c.6121G>A p.E2041K | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV65279572; called by muse, mutect2, varscan2
- CENPF | c.7807G>A p.D2603N | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.199); catalogued as COSV65279580; called by muse, mutect2, varscan2
- CENPJ | c.3737C>T p.T1246M | Missense Mutation (SNP) | VAF 56/237 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs767833776, COSV55036267; called by muse, mutect2, varscan2
- CENPJ | c.3229C>T p.R1077* | Nonsense Mutation (SNP) | VAF 46/183 reads (25%) | catalogued as rs763373509, COSV67883316; called by muse, varscan2
- CENPK | c.291C>T p.F97= | Splice Region (SNP) | VAF 39/183 reads (21%) | catalogued as COSV54469818; called by muse, mutect2, varscan2
- CENPK | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 151/580 reads (26%) | catalogued as COSV54467811; called by muse, mutect2, varscan2
- CENPM | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs763500522, COSV53246056; called by muse, mutect2
- CEP120 | c.2943A>C p.K981N | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs1388103552, COSV60268965; called by muse, mutect2, varscan2
- CEP126 | c.208C>T p.R70* | Nonsense Mutation (SNP) | VAF 39/258 reads (15%) | catalogued as COSV54827338, COSV54831336; called by muse, mutect2, varscan2
- CEP126 | c.1634C>T p.S545F | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs756185753, COSV54831351; called by muse, mutect2, varscan2
- CEP128 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs561372195, COSV53676499; called by mutect2, varscan2
- CEP135 | c.2203G>A p.E735K | Missense Mutation (SNP) | VAF 58/444 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748311087, COSV57263213, COSV99954855; called by mutect2, varscan2
- CEP152 | c.2745A>C p.E915D | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as COSV57865450; called by muse, mutect2, varscan2
- CEP152 | c.1137G>T p.K379N | Missense Mutation (SNP) | VAF 42/211 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as rs1453843365, COSV57861618; called by muse, mutect2, varscan2
- CEP170 | c.4207C>T p.R1403W | Missense Mutation (SNP) | VAF 67/340 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747106206, COSV60515578; called by muse, mutect2, varscan2
- CEP170 | c.1273-8C>A | Splice Region (SNP) | VAF 14/182 reads (8%) | catalogued as COSV60508721; called by muse, mutect2
- CEP170 | c.491C>A p.A164D | Missense Mutation (SNP) | VAF 34/226 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV60515593; called by muse, mutect2, varscan2
- CEP20 | c.437G>T p.R146I | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.388); catalogued as rs905421942, COSV55384157; called by muse, mutect2, varscan2
- CEP250 | c.3134G>A p.R1045Q | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs763406705, COSV61168241; called by muse, mutect2, varscan2
- CEP290 | c.4394G>A p.R1465Q | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs576877716, COSV58356962; called by muse, mutect2, varscan2
- CEP295 | c.1336+1G>A p.X446_splice | Splice Site (SNP) | VAF 8/80 reads (10%) | catalogued as COSV57353240; called by muse, mutect2
- CEP57 | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 34/156 reads (22%) | catalogued as rs778077296, COSV57690764; called by muse, mutect2, varscan2
- CEP57L1 | c.1059T>G p.S353R | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV61246428; called by muse, mutect2, varscan2
- CEP63 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 75/316 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV59679780; called by muse, mutect2, varscan2
- CEP78 | c.2023A>G p.N675D (on ENST00000424347 / NM_001349840.2; = p.N676D on NM_032171.3) | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); catalogued as COSV52850756; called by muse, mutect2, varscan2
- CEP85L | c.1708A>C p.K570Q | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV63829133; called by muse, mutect2, varscan2
- CEP95 | c.2285C>T p.A762V | Missense Mutation (SNP) | VAF 40/227 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.306); catalogued as COSV73609663; called by muse, mutect2, varscan2
- CER1 | c.393G>T p.K131N | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV101097776, COSV66604017; called by muse, mutect2, varscan2
- CERT1 | c.638G>A p.R213Q (on ENST00000405807 / NM_001130105.1; = p.R85Q on NM_005713.3) | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54665276; called by muse, mutect2, varscan2
- CFAP251 | c.3200G>A p.R1067Q | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1428337065, COSV56611369; called by muse, mutect2, varscan2
- CFAP43 | c.3139C>T p.R1047* | Nonsense Mutation (SNP) | VAF 24/133 reads (18%) | catalogued as COSV53377997; called by muse, mutect2, varscan2
- CFAP43 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV53381798; called by muse, mutect2, varscan2
- CFAP44 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs370318076; called by muse, mutect2, varscan2
- CFAP47 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 51/101 reads (50%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs780374404, COSV52880535, COSV52882723; called by muse, mutect2, varscan2
- CFAP53 | c.673G>T p.E225* | Nonsense Mutation (SNP) | VAF 74/289 reads (26%) | catalogued as COSV68352931; called by muse, mutect2, varscan2
- CFAP61 | c.3263G>A p.R1088Q | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.677); catalogued as rs760689597, COSV55620168, COSV55632747; called by muse, mutect2, varscan2
- CHAT | c.936C>A p.F312L | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.688); catalogued as rs1442234888, COSV60334175; called by muse, mutect2, varscan2
- CHCHD6 | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs779753384, COSV99336021; called by muse, mutect2, varscan2
- CHD3 | c.62C>A p.S21Y | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as COSV57874583; called by muse, mutect2
- CHD3 | c.2031G>T p.K677N | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.951); catalogued as COSV57881098; called by muse, mutect2, varscan2
- CHD9 | c.8116A>C p.N2706H (on ENST00000398510 / NM_001382353.1; = p.N2690H on NM_025134.7) | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as COSV54617270; called by muse, mutect2, varscan2
- CHGB | c.485G>T p.R162I | Missense Mutation (SNP) | VAF 76/353 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.211); catalogued as COSV66761934; called by muse, mutect2, varscan2
- CHI3L1 | c.282G>C p.L94F | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55140340; called by muse, mutect2, varscan2
- CHI3L2 | c.292C>A p.L98I | Missense Mutation (SNP) | VAF 49/274 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1039610150, COSV63874430; called by muse, mutect2, varscan2
- CHMP2A | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs376979258; called by muse, mutect2, varscan2
- CHMP4C | c.21C>A p.F7L | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755091245; called by muse, mutect2, varscan2
- CHORDC1 | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 83/418 reads (20%) | catalogued as COSV100272155, COSV57706659; called by muse, mutect2, varscan2
- CHRM2 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs768531848, COSV57767335, COSV57769152; called by muse, mutect2, varscan2
- CHRM3 | c.627C>A p.Y209* | Nonsense Mutation (SNP) | VAF 72/370 reads (19%) | catalogued as COSV55106645; called by muse, mutect2, varscan2
- CHRNA6 | c.1268C>T p.S423L | Missense Mutation (SNP) | VAF 92/403 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs139568359, COSV52379861, COSV52381216; called by muse, mutect2, varscan2
- CHRNB1 | c.1238C>T p.A413V | Missense Mutation (SNP) | VAF 44/237 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.119); catalogued as COSV60142537; called by muse, mutect2, varscan2
- CHRND | c.510T>C p.S170= | Splice Region (SNP) | VAF 18/96 reads (19%) | catalogued as COSV99285464; called by muse, mutect2, varscan2
- CHST11 | c.1028A>G p.Y343C | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57995765; called by muse, mutect2, varscan2
- CHST9 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.447); catalogued as COSV52450361; called by muse, mutect2, varscan2
- CHTF18 | c.1882G>A p.A628T | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs760424990, COSV50210363; called by muse, mutect2, varscan2
- CIART | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 100/436 reads (23%) | catalogued as COSV51746327, COSV99290205; called by mutect2, varscan2
- CIB3 | c.338A>G p.K113R | Missense Mutation (SNP) | VAF 58/221 reads (26%) | SIFT tolerated (0.95); PolyPhen benign (0.015); catalogued as COSV99521987; called by muse, mutect2, varscan2
- CILK1 | c.156+2T>C p.X52_splice | Splice Site (SNP) | VAF 49/199 reads (25%) | catalogued as COSV100608088; called by muse, mutect2, varscan2
- CIP2A | c.293A>C p.N98T | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV99843207; called by muse, mutect2
- CIR1 | c.69A>C p.K23N | Missense Mutation (SNP) | VAF 73/366 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV55810169; called by muse, varscan2
- CIT | c.3184C>T p.R1062* | Nonsense Mutation (SNP) | VAF 41/169 reads (24%) | catalogued as COSV55884837; called by muse, mutect2, varscan2
- CKAP5 | c.873A>C p.K291N | Missense Mutation (SNP) | VAF 26/354 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100370531, COSV100371531; called by muse, mutect2
- CLASP1 | c.4087C>T p.R1363* | Nonsense Mutation (SNP) | VAF 26/120 reads (22%) | catalogued as COSV55313295; called by muse, mutect2, varscan2
- CLC | c.257G>A p.G86D | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.909); catalogued as rs756972983, COSV55685242; called by muse, mutect2, varscan2
- CLCA1 | c.1172C>T p.S391L | Missense Mutation (SNP) | VAF 54/242 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs772377825, COSV52331848; called by muse, mutect2, varscan2
- CLCA4 | c.160-1G>T p.X54_splice | Splice Site (SNP) | VAF 40/255 reads (16%) | catalogued as COSV99760862; called by muse, mutect2, varscan2
- CLCN1 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 66/206 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs889073641, CM110545, COSV58368676; called by muse, mutect2, varscan2
- CLCN3 | c.968C>A p.S323Y | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61628748; called by muse, mutect2, varscan2
- CLEC18B | c.284G>A p.S95N | Missense Mutation (SNP) | VAF 79/633 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100376169; called by muse, mutect2, varscan2
- CLEC4C | c.407G>T p.R136I | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as rs759515484, COSV63582651, COSV63583304; called by muse, mutect2, varscan2
- CLEC4F | c.824G>T p.R275I | Missense Mutation (SNP) | VAF 23/356 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as COSV55478546; called by muse, mutect2
- CLEC4F | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 53/201 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV55481873, COSV99713604; called by muse, mutect2, varscan2
- CLECL1 | c.383A>C p.K128T | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as COSV59932182; called by muse, mutect2, varscan2
- CLIP1 | c.3263C>T p.A1088V (on ENST00000620786 / NM_001247997.1; = p.A1077V on NM_002956.2) | Missense Mutation (SNP) | VAF 97/472 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.942); catalogued as rs781272448; called by muse, mutect2, varscan2
- CLIP1 | c.569A>C p.K190T | Missense Mutation (SNP) | VAF 49/475 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV56809291; called by muse, mutect2
- CLIP4 | c.1733G>T p.R578I | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.174); catalogued as COSV60753220; called by muse, mutect2, varscan2
- CLNK | c.465G>T p.K155N | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.024); catalogued as COSV57019424; called by muse, mutect2
- CLOCK | c.1460C>T p.S487F | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as rs779397098, COSV59405185; called by muse, mutect2, varscan2
- CLOCK | c.706A>G p.T236A | Missense Mutation (SNP) | VAF 13/167 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100012054; called by muse, mutect2
- CLRN1 | c.588T>G p.F196L | Missense Mutation (SNP) | VAF 144/502 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.266); catalogued as COSV55807049; called by muse, varscan2
- CLTC | c.3259G>T p.E1087* | Nonsense Mutation (SNP) | VAF 30/143 reads (21%) | catalogued as COSV52253625; called by muse, mutect2, varscan2
- CLUAP1 | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100489821; called by muse, mutect2, varscan2
- CMAS | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 54/203 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.318); catalogued as rs753560501, COSV57556336; called by muse, mutect2, varscan2
- CMC4 | c.45G>T p.Q15H | Missense Mutation (SNP) | VAF 28/294 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62900804; called by muse, mutect2
- CMTR1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV65089699; called by muse, mutect2, varscan2
- CMYA5 | c.1168T>C p.F390L | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV71409940; called by muse, mutect2, varscan2
- CMYA5 | c.3431C>A p.S1144* | Nonsense Mutation (SNP) | VAF 18/97 reads (19%) | catalogued as COSV71409946; called by muse, mutect2, varscan2
- CMYA5 | c.11558C>A p.S3853Y | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs907830031, COSV69746273; called by muse, mutect2, varscan2
- CNBD1 | c.426G>T p.K142N | Missense Mutation (SNP) | VAF 14/258 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1330613877, COSV72916988; called by muse, mutect2
- CNDP2 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60841836; called by muse, mutect2, varscan2
- CNGA1 | c.6G>T p.K2N | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV62054217, COSV62055971; called by muse, mutect2, varscan2
- CNGA4 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 85/360 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.222); catalogued as COSV56415185; called by muse, mutect2, varscan2
- CNGB1 | c.3596C>A p.S1199Y | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as rs767160156, COSV99212263; called by muse, mutect2, varscan2
- CNGB3 | c.1264T>G p.F422V | Missense Mutation (SNP) | VAF 59/232 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV60699294; called by muse, mutect2, varscan2
- CNMD | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 107/472 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV65034222; called by muse, mutect2, varscan2
- CNNM1 | c.2531G>A p.R844H | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs143111634; called by muse, mutect2, varscan2
- CNOT1 | c.4949G>A p.R1650Q | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV55317545; called by muse, varscan2
- CNOT10 | c.1585G>T p.E529* | Nonsense Mutation (SNP) | VAF 32/179 reads (18%) | catalogued as COSV59395740; called by muse, mutect2, varscan2
- CNOT11 | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 25/409 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.175); catalogued as rs1383777591; called by muse, mutect2
- CNOT4 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.81); catalogued as rs1308899779, COSV59651637; called by muse, mutect2, varscan2
- CNOT6 | c.1636C>T p.P546S | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV99993886; called by muse, mutect2
- CNOT7 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as COSV61352502; called by muse, varscan2
- CNPY1 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.742); catalogued as rs1344924963, COSV58786479; called by muse, mutect2, varscan2
- CNTF | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 48/260 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs761605079, COSV60162305; called by muse, varscan2
- CNTN5 | c.125C>A p.S42Y | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.123); catalogued as COSV54343863, COSV54359917, COSV99682022; called by mutect2, varscan2
- CNTNAP4 | c.2516T>G p.F839C | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56702670; called by muse, mutect2
- CNTNAP5 | c.557G>T p.R186L | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV70514569; called by muse, mutect2, varscan2
- CNTNAP5 | c.1040G>A p.R347Q | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.994); catalogued as rs369591290, COSV70510307; called by muse, mutect2
- CNTRL | c.4135G>T p.E1379* | Nonsense Mutation (SNP) | VAF 90/386 reads (23%) | catalogued as COSV53054120; called by muse, mutect2, varscan2
- CNTROB | c.2130G>T p.K710N | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.836); catalogued as COSV66607893, COSV66608066; called by muse, mutect2, varscan2
- COA8 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.765); catalogued as rs756550363, COSV56029897; called by muse, mutect2, varscan2
- COBLL1 | c.2310A>C p.K770N (on ENST00000392717; = p.K732N on NM_014900.5) | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV52077169; called by muse, mutect2, varscan2
- COG5 | c.187A>C p.K63Q | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.484); catalogued as COSV51765777; called by muse, mutect2, varscan2
- COG6 | c.803A>C p.E268A | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV62998429; called by muse, mutect2, varscan2
- COL12A1 | c.6074G>A p.R2025H | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs34336755; called by muse, mutect2, varscan2
- COL12A1 | c.1487A>G p.K496R | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV59409410; called by muse, varscan2
- COL14A1 | c.2579G>A p.R860K | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0.306); catalogued as COSV99920921; called by muse, mutect2
- COL15A1 | c.4014C>A p.Y1338* | Nonsense Mutation (SNP) | VAF 32/117 reads (27%) | catalogued as COSV66649860; called by muse, mutect2, varscan2
- COL16A1 | c.517C>A p.L173M | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54708276; called by muse, mutect2, varscan2
- COL1A1 | c.2728C>T p.R910C | Missense Mutation (SNP) | VAF 68/206 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs886440452, COSV56809996; called by muse, mutect2, varscan2
- COL21A1 | c.1029G>A p.T343= | Splice Region (SNP) | VAF 16/113 reads (14%) | catalogued as rs373532211; called by muse, mutect2
- COL21A1 | c.737G>T p.R246I | Missense Mutation (SNP) | VAF 49/255 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV55158346; called by muse, mutect2, varscan2
- COL21A1 | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.121); catalogued as COSV55182069; called by muse, mutect2
- COL27A1 | c.2069A>C p.K690T | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61931201; called by muse, mutect2, varscan2
- COL27A1 | c.2956C>T p.R986W | Missense Mutation (SNP) | VAF 122/559 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs751641724, COSV61931207; called by muse, varscan2
- COL27A1 | c.4384G>A p.D1462N | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs1481554721, COSV61930343; called by muse, mutect2, varscan2
- COL2A1 | c.50T>C p.V17A | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV100477690; called by muse, varscan2
- COL4A1 | c.327A>C p.G109= | Splice Region (SNP) | VAF 21/106 reads (20%) | catalogued as COSV65432689; called by muse, mutect2, varscan2
- COL4A2 | c.4969G>A p.E1657K | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1232600556, COSV64629364; called by muse, mutect2
- COL4A6 | c.1648C>A p.L550I | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV57860901; called by muse, mutect2, varscan2
- COL5A1 | c.1389G>A p.P463= | Splice Region (SNP) | VAF 62/309 reads (20%) | catalogued as rs1057518771, COSV65671787; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A1 | c.3235C>T p.P1079S | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763310793; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A2 | c.3308C>T p.P1103L | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as rs150401168; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A1 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs764704372; called by muse, mutect2, varscan2
- COL6A2 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs756242788, COSV100153466; called by mutect2, varscan2
- COL6A2 | c.2180C>T p.A727V | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.431); catalogued as rs1408523098, COSV56000808; called by muse, mutect2
- COL6A3 | c.8821G>A p.A2941T | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV99800014; called by muse, mutect2, varscan2
- COL6A3 | c.6511G>A p.G2171R | Missense Mutation (SNP) | VAF 74/329 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55090010, COSV99797982; called by muse, mutect2, varscan2
- COL6A3 | c.2804G>A p.R935Q | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762016120, COSV55112550; called by muse, mutect2, varscan2
- COL6A3 | c.715G>T p.D239Y | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV55085019; called by muse, mutect2, varscan2
- COL6A5 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 58/315 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as COSV55196593, COSV99594756; called by muse, varscan2
- COL6A5 | c.765G>T p.Q255H | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV55203469; called by muse, mutect2
- COL6A5 | c.2254C>T p.R752W | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1393082594, COSV55199959; called by muse, mutect2, varscan2
- COL6A5 | c.3862C>T p.R1288W | Missense Mutation (SNP) | VAF 55/208 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs915176448, COSV55204850, COSV55206533; called by muse, mutect2, varscan2
- COL6A6 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 100/515 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as rs201898554, COSV62023536; called by muse, mutect2, varscan2
- COL6A6 | c.2176C>A p.L726I | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62039101; called by muse, mutect2, varscan2
- COL8A1 | c.11T>G p.L4R | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.017); catalogued as COSV53743669; called by muse, mutect2, varscan2
- COL9A1 | c.2065G>T p.E689* | Nonsense Mutation (SNP) | VAF 44/212 reads (21%) | catalogued as COSV57894300; called by muse, varscan2
- COLGALT2 | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777342761, COSV62298603; called by muse, mutect2, varscan2
- COLGALT2 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.087); catalogued as rs368641256, COSV62728112; called by muse, mutect2
- COMMD2 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 62/212 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779093793, COSV101519909, COSV71946699; called by muse, mutect2
- COMMD8 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.86); catalogued as rs1275304908, COSV67500808; called by muse, mutect2, varscan2
5,269 further variants in this file (3,546 protein-altering or splice-affecting, 1,204 silent, 519 other) are not listed here.
